CCDI case PBCWHY — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS.
https://portal.gdc.cancer.gov/cases/207c5712-092e-4a60-aa56-7acefac20254

Demographics
Sex at birth: female.

Biospecimens (3 samples)
- Sample 0E1KO8: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0E1KOF: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0E1KOV: Tissue type: Tumor; Specimen type: Solid Tissue.
